Somatic mutation profile of tumor specimen 0DJKKO from CCDI case PBBWMI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.2 years (3,005 days).
Specimen 0DJKKO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cdf0e2b-f02c-4f8b-995b-5c62592d81ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJKK7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b209bd97-8786-4810-9d70-2350521a670e

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 2, 3'UTR 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 145/877 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 296/624 reads (47%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 201/908 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CYP11A1 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 140/636 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs773145475, COSV51430875, COSV99165888; called by muse, mutect2, varscan2
- OR9A4 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 277/1180 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV71884946; called by muse, mutect2, varscan2
- PCDHGA6 | c.28C>A p.R10S | Missense Mutation (SNP) | VAF 181/873 reads (21%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV99528851, COSV99535132; called by muse, mutect2, varscan2
- PRL | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 221/978 reads (23%) | catalogued as rs757549608; called by muse, mutect2, varscan2
- CD177 | c.294C>G p.I98M | Missense Mutation (SNP) | VAF 54/501 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- DCC | c.2951A>C p.Y984S | Missense Mutation (SNP) | VAF 67/641 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM47B | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 117/927 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- MTUS1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 67/725 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- NEMP1 | c.846G>T p.W282C (on ENST00000300128 / NM_001130963.2; = p.W209C on NM_015257.3) | Missense Mutation (SNP) | VAF 287/806 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGT2B4 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 52/1912 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ZRANB3 | c.2118A>C p.K706N | Missense Mutation (SNP) | VAF 253/1327 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC120 | c.267C>T p.A89= | Silent (SNP) | VAF 24/847 reads (3%) | called by muse, mutect2
- GSDME | c.1119C>T p.G373= | Silent (SNP) | VAF 20/600 reads (3%) | called by muse, mutect2
- HIVEP3 | c.2169C>T p.D723= | Silent (SNP) | VAF 77/614 reads (13%) | catalogued as rs201664303; called by muse, mutect2, varscan2
- NAIP | c.414C>T p.Y138= | Silent (SNP) | VAF 169/629 reads (27%) | catalogued as rs759032459, COSV52000721; called by muse, mutect2, varscan2
- ARMH1 | c.725-15T>A | Intron (SNP) | VAF 73/697 reads (10%) | called by muse, mutect2, varscan2
- KLHDC1 | c.*4G>T | 3'UTR (SNP) | VAF 118/482 reads (24%) | called by muse, mutect2, varscan2
- LRRC40 | c.*49T>A | 3'UTR (SNP) | VAF 137/409 reads (33%) | called by muse, mutect2, varscan2
- TMEM18 | c.57+84G>C | Intron (SNP) | VAF 74/252 reads (29%) | called by mutect2, varscan2
